Gene-level copy-number profile of tumor specimen HCM-SANG-0289-C15-08A-01D-A80T-32 from HCMI case HCM-SANG-0289-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0289-C15-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ba54d862-013b-4b8b-81f1-7614fa1d5a22.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0289-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/d8450191-fd0f-434e-9b1e-925879e91a6e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 344; copy number 1: 180; copy number 2: 5,225; copy number 3: 11,325; copy number 4: 36,681; copy number 5: 3,129; copy number 6: 1,775; copy number 7: 78; copy number 8: 10; copy number 10: 39; copy number 12: 72; copy number 13: 20; copy number 14: 23; copy number 15: 1; copy number 19: 2; copy number 23: 4; copy number 76: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 166 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:11,486,894–11,839,304, 9 genes, copy number 14–76: BLK, AC022239.1, LINC00208, GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1.
- chr8:29,067,278–29,263,124, 1 gene, copy number 13 (within-gene range 3–13): KIF13B.
- chr8:29,110,573–29,953,724, 15 genes, copy number 10–13: AC108449.1, HMGB1P23, DUSP4, AC084262.2, AC084262.1, AC084026.2, AC084026.1, AC084026.3, RPL17P33, LINC00589, LINC02099, AC131254.1, AC131254.3, AC131254.2, LINC02209.
- chr8:37,784,191–38,213,301, 21 genes, copy number 14: ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2.
- chr8:41,032,892–41,896,762, 21 genes, copy number 10 (within-gene range 7–10): RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1.
- chr10:32,887,273–35,572,669, 40 genes, copy number 10–12: ITGB1, AK3P5, ITGB1-DT, MTND4LP11, RN7SL847P, AL365203.1, RPL7AP53, IATPR, NRP1, AL121748.1, RN7SL398P, AL353600.1, LINC02628, AL450313.1, LINC00838, RPL23P11, LINC02629, PARD3, Y_RNA, ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1.
- chr10:35,778,302–36,442,392, 7 genes, copy number 10–23: PCAT5, LINC02630, AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2.
- chr10:36,940,109–37,544,701, 12 genes, copy number 12–15: AL390061.1, MKNK2P1, ARL6IP1P2, ANKRD30A, RNU6-811P, AL157387.1, LINC00993, RN7SL314P, Y_RNA, TMEM161BP1, VN1R53P, TACC1P1.
- chr18:21,612,314–23,026,488, 40 genes, copy number 12–13: SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 12. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
